CPTAC case C3L-02970 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba037761-7166-40e1-8f27-1c1561a18b9c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1959; Vital status: Dead; Days to death: 381 days (1.0 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 58.9 years (21,524 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 381 days (1.0 years); Progression or recurrence: no; Days to last follow up: 381 days (1.0 years).
   Pathology details: Greatest tumor dimension: 3 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Targeted Molecular Therapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 298 days; Disease response: With Tumor.
- Days to follow up: 381 days (1.0 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 93.89 kg; Height: 172.72 cm; BMI: 31.47.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 30; Cigarettes per day: 20; Tobacco smoking onset year: 1987; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 35.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02970-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 262 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02970-23: Section location: Temporal Lobe; Percent tumor nuclei: 55; Percent necrosis: 20.
- Sample C3L-02970-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
